Gene-level copy-number profile of tumor specimen TCGA-BT-A20W-01A from TCGA case TCGA-BT-A20W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 71.4 years (26,078 days).
Specimen TCGA-BT-A20W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ef81f6ea-a845-4f71-a60a-8922034e83df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20W-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c9c0c89-4bb9-41cd-bc3b-87d011fa4d2c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,017; copy number 2: 20,570; copy number 3: 34,574; copy number 4: 1,970; copy number 5: 693; copy number 6: 671; copy number 7: 166; copy number 8: 2; copy number 9: 3; copy number 10: 74; copy number 11: 38; copy number 12: 25; copy number 13: 2; copy number 14: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20W-01A-21D-A14V-01): tumor purity 0.72, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 319 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,487,364–150,975,534, 30 genes, copy number 7: TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51, SETDB1, CERS2, AL590133.2, AL590133.1.
- chr5:58,198–4,041,764, 94 genes, copy number 7–10 (broad region; genes not listed).
- chr5:5,688,805–5,694,742, 1 gene, copy number 14: AC026736.1.
- chr5:10,082,571–14,877,919, 66 genes, copy number 7–11 (broad region; genes not listed).
- chr8:41,490,396–42,271,266, 25 genes, copy number 12 (within-gene range 3–12): GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1.
- chr8:99,873,200–100,958,180, 34 genes, copy number 7: COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P.
- chr8:129,415,949–129,484,142, 2 genes, copy number 8: AC011257.1, MIR3686.
- chr12:990,509–1,495,933, 1 gene, copy number 14 (within-gene range 6–14): ERC1.
- chr12:1,380,060–1,660,380, 6 genes, copy number 14: AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649.
- chr12:1,695,830–1,698,044, 1 gene, copy number 14: AC005183.1.
- chr12:1,917,951–1,936,574, 2 genes, copy number 13: AC005342.2, LINC00940.
- chr12:2,659,937–4,118,132, 47 genes, copy number 7: AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1.
- chr21:44,627,093–44,698,044, 10 genes, copy number 7: KRTAP10-9, KRTAP10-10, KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2, IMMTP1, KRTAP12-1, KRTAP12-6P, KRTAP10-12.

Autosomal genes at a single copy (total copy number 1): 562. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
